Gene-level copy-number profile of tumor specimen HTMCP-03-06-02434-01A from CGCI case HTMCP-03-06-02434, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 31.7 years (11,578 days).
Specimen HTMCP-03-06-02434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 52c7dd52-b4a2-4cbd-9e53-8c942eb8c6ba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02434-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,259 have no estimate.
https://portal.gdc.cancer.gov/files/1e52da22-45aa-43df-bca0-4c98c8a319e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 6,987; copy number 2: 47,874; copy number 3: 3,011; copy number 4: 153; copy number 5: 26; copy number 6: 58; copy number 7: 26; copy number 13: 6; copy number 15: 73; copy number 16: 47; copy number 17: 31; copy number 18: 51; copy number 20: 9.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes (within-gene range 0–2): TTC34, AC242022.2, AC242022.1.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 327 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,173,433–56,524,495, 1 gene, copy number 15 (within-gene range 2–15): AC119674.2.
- chr1:56,414,935–64,693,058, 119 genes, copy number 15–16 (broad region; genes not listed).
- chr1:143,419,625–143,846,504, 22 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2.
- chr1:153,534,599–153,550,136, 4 genes, copy number 5 (within-gene range 3–5): S100A6, S100A5, S100A4, S100A3.
- chr7:38,239,580–38,330,935, 14 genes, copy number 6 (within-gene range 4–6): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr14:22,086,407–22,483,069, 45 genes, copy number 6–7: TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr18:2,537,525–8,832,778, 121 genes, copy number 6–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,987. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
